Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A4RY, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A4RY-01A (Primary Tumor).

[page 1 of 4]
Name:	[REDACTED]	Age/Sex:	/F	Location:	[REDACTED]
Acct#:	[REDACTED]	Unit#:	[REDACTED]	Status:	[REDACTED]
Reg:	[REDACTED]	Disch:	[REDACTED]	Att Dr:	[REDACTED]
				Room/Bed:	[REDACTED]

Specimen:	Received:	) Status:	Req#:
	Collected:	) Sp type: SURGICAL P	
	Subm Dr:	M.D.	

PREOPERATIVE DIAGNOSIS

BREAST CANCER, BENIGN MAMMARY DYSPLASIA

1CD-0-3
Carcinoma, infiltrating lobular, NOS
8520/3

OPERATION PERFORMED

Site: breast, NOS C50.9

DATE:
DOCTOR(S):
PROCEDURE: MASTECTOMY MODIFIED RADICAL/TOTAL MASTECTOMY

TISSUE REMOVED

- A. RIGHT AXILLARY LYMPH NODE LEVEL 2
- B. RIGHT AXILLARY LYMPH NODE LEVEL 3
- C. LEFT MASTECTOMY STITCH AT
- D. RIGHT MODIFIED RADICAL MASTECTOMY STITCH AT

GROSS DESCRIPTION

RECEIVED IN 4 PARTS.

PART A RECEIVED LABELED [REDACTED] RIGHT AXILLARY LEVEL 2 LYMPH NODES IS A NODULAR PORTION OF YELLOW FATTY TISSUE MEASURING 3.7 X 2.2 X 0.7 CM IN GREATEST DIMENSION. FOUR FIRM OVOID STRUCTURES ARE IDENTIFIED MEASURING FROM 0.4 TO 1 CM IN GREATEST DIMENSION. THE LARGER NODES ARE EACH SECTIONED AND GROSSLY POSITIVE. ONE-HALF OF EACH OF THESE IS SUBMITTED ALONG WITH THE UNSECTIONED SMALLER NODE LABELED A. THE REMAINING NODAL TISSUE IS SUBMITTED PER CLINICAL BREAST CARE PROJECT RESEARCH PROTOCOL LABELED P1-P3.

PART B RECEIVED LABELED [REDACTED] RIGHT AXILLARY LEVEL 3 LYMPH NODE IS A FIRM 0.8 CM IN GREATEST DIMENSION NODULE AND AN IRREGULAR PORTION OF NODULAR YELLOW FATTY TISSUE MEASURING 6 X 1.5 X 0.7 CM. FIVE FIRM OVOID STRUCTURES ARE IDENTIFIED IN THIS PORTION OF FATTY TISSUE. THREE OF THE NODULES ARE SUBMITTED UNSECTIONED LABELED B1. ONE-HALF FROM 2 SEPARATE GROSSLY POSITIVE NODES ARE SUBMITTED IN B2 WITH THE REMAINING TISSUE FROM THESE 2 NODES SUBMITTED AS P4. THE LARGEST NODE MEASURING 1.4 CM IN GREATEST DIMENSION IS GROSSLY FOCALLY POSITIVE. THIS IS SUBMITTED BISECTED AS B3.

PART C RECEIVED LABELED [REDACTED] LEFT MASTECTOMY STITCH AT 12 O'CLOCK IS A 1310 GRAM SIMPLE MASTECTOMY MEASURING 23 CM FROM MEDIAL TO LATERAL, 23.5 CM FROM SUPERIOR TO INFERIOR, AND UP TO 5.5 CM FROM

[page 2 of 4]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req#: [REDACTED]

Collected:

Sp type: SURGICAL P

Subm Dr:

M.D.

GROSS DESCRIPTION

(Continued)

ANTERIOR TO DEEP. THE NIPPLE IS UNREMARKABLE WITHIN A 14 X 5 CM SKIN ELLIPSE. A SUTURE DENOTES 12 O'CLOCK. THE ANTERIOR ASPECT IS MARKED WITH BLUE INK, THE DEEP MARGIN WITH BLACK. SECTIONING REVEALS THE CENTRAL 50% OF THE SPECIMEN TO CONSIST OF DENSE TAN FIBROUS TISSUE. THIS IS SURROUNDED BY A PERIMETER OF YELLOW FATTY TISSUE. NO MASSES ARE IDENTIFIED. REPRESENTATIVE SECTIONS ARE SUBMITTED AS FOLLOWS: C1--NIPPLE, C2--CENTRAL DEEP MARGIN, C3 AND 4--UPPER OUTER QUADRANT, C5 AND 6--UPPER INNER QUADRANT, C7 AND 8--LOWER INNER QUADRANT, C9 AND 10--LOWER OUTER QUADRANT. ADDITIONALLY WITHIN THE CONTAINER AND INCLUDED THE WEIGHT ARE ADDITIONAL MULTIPLE IRREGULAR FRAGMENTS OF YELLOW-RED FATTY TISSUE IN AGGREGATE MEASURING 10 X 10 X 2.3 CM. SECTIONING REVEALS BLAND YELLOW FATTY TISSUE AND REPRESENTATIVE SECTIONS ARE SUBMITTED LABELED C11 THROUGH 13.

NOTE: MIRROR IMAGE SECTIONS OF THE NIPPLE ARE SUBMITTED AS P15 AND MIRROR IMAGE SECTIONS TO C3, C5, C7, AND C9 ARE SUBMITTED FROZEN IN OCT PER CLINICAL BREAST CARE PROJECT RESEARCH PROTOCOL.

PART D RECEIVED LABELED [REDACTED] RIGHT MODIFIED RADICAL MASTECTOMY STITCH AT 12 O'CLOCK IS A 1460 GRAM RIGHT MODIFIED RADICAL MASTECTOMY. THE MASTECTOMY PORTION MEASURES 24.5 CM FROM MEDIAL TO LATERAL, 26 CM FROM SUPERIOR TO INFERIOR, AND UP TO 6.5 CM FROM ANTERIOR TO POSTERIOR. THE AXILLARY PORTION MEASURES 10 X 9 X 2.5 CM. THE ANTERIOR MARGIN IS MARKED BLUE. THE DEEP IS MARKED BLACK. THE NIPPLE IS UNREMARKABLE AND SITS IN THE MORE SUPERIOR PORTION OF THE SKIN ELLIPSE. THE SKIN ELLIPSE MEASURES 14 X 5.5 CM. THE 12 O'CLOCK SUTURE IS JUST TO THE MEDIAL SIDE OF THE AREOLA. THE AXILLARY TAIL IS REMOVED AND RED INK IS PLACED IN THIS AREA TO INDICATE THAT IT IS NOT TRUE MARGIN. UPON A QUICK PALPATION OF THE AXILLARY TAIL THREE ARE 3 PROMINENT STRUCTURES. THE 1ST IS A 0.8 CM IN GREATEST DIMENSION LYMPH NODE WHICH IS GROSSLY NEGATIVE AND IS SUBMITTED BISECTED AS D1. THE 2ND IS A 2.5 CM GROSSLY NEGATIVE NODAL STRUCTURE SUBMITTED BISECTED AS D2. THE 3RD STRUCTURE IS A 3.8 CM IN GREATEST DIMENSION GROSSLY POSITIVE LYMPH NODE OF WHICH ONE FULL CROSS SECTION IS SUBMITTED IN D3 AND 4. A COIL CLIP IS IDENTIFIED AND THE AREA OF THE CLIP IS SUBMITTED IN D5. THIS IS THE SAME NODE AS D3 AND 4. PORTIONS OF THIS LARGEST NODE ARE ALSO SUBMITTED IN P5 AND 6. SECTIONING REVEALS THE CENTRAL PORTION OF THE BREAST TO CONSIST OF DENSE TAN FIBROUS TISSUE AND THIS EXTENDS TO AN ILL-DEFINED GRAY-TAN MASS AT 9 O'CLOCK WHICH MEASURES 5.5 CM FROM MEDIAL TO LATERAL, 8 CM FROM SUPERIOR TO INFERIOR BY PALPATION, AND 4.5 CM FROM ANTERIOR TO POSTERIOR. GROSSLY IT IS 1 CM FROM BOTH THE ANTERIOR AND DEEP MARGIN. SECTIONS ARE SUBMITTED AS FOLLOWS: D6--NIPPLE, D7 THROUGH D9--SECTIONS OF DEEP MARGIN BENEATH LESION, D10 THROUGH D14--A CONTINUOUS SECTION OF THE LESION FROM SUPERIOR TO INFERIOR WHERE THE RED ENDS ARE

[page 3 of 4]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

eq#: [REDACTED]

Collected:

Sp type: SURGICAL P

Subm Dr:

.D.

GROSS DESCRIPTION

(Continued)

THE AREA WHERE THE ONE STRIP WAS SEPARATED FROM THE ADJACENT SECTION, D15--SECTION OF THE FAR LATERAL PORTION OF THE GROSS LESION, D16--SECTION FROM THE FAR MEDIAL PORTION OF THE GROSS LESION, D17--TISSUE DEEP TO THE 5 CROSS SECTIONS, D18--TISSUE ANTERIOR TO TE 5 CROSS SECTIONS, D19--RANDOM SECTION OF LESION FROM THE MIDPORTION, D20--RANDOM TUMOR INFERIOR-EDGE, D21--UPPER INNER QUADRANT 2 CM FROM GROSS TUMOR, D22--UPPER OUTER QUADRANT 3 CM FROM GROSS TUMOR, D23--LOWER OUTER QUADRANT 3 CM FROM GROSS TUMOR, D24--LOWER INNER QUADRANT 5 CM FROM GROSS TUMOR.

FURTHER EXAMINATION OF THE AXILLARY TAIL: EIGHTEEN (18) ADDITIONAL NODAL STRUCTURES ARE IDENTIFIED. THESE ARE SUBMITTED AS FOLLOWS: D25--6 NODES NOT SECTIONED, D26--ONE-HALF OF 2 GROSSLY POSITIVE LYMPH NODES PLUS 1 GROSSLY FAT REPLACED LYMPH NODE, BISECTED, D27--4 NODES, EACH BISECTED, D28--2 NODES, EACH BISECTED, D29--3 NODES, EACH BISECTED.

SECTIONS PER CLINICAL BREAST CARE RESEARCH PROTOCOL ARE SUBMITTED FROM THE LYMPH NODE WITH THE CLIP LABELED P5 AND P6; TWO OF THE GROSSLY POSITIVE LYMPH NODES IN CASSETTE D26 AS P16; AND SECTIONS OF THE TUMOR AS P7 THROUGH P14 WITH MIRROR IMAGE SECTIONS FROZEN IN OCT OF P7, P8, P9, AND 013 AS WELL AS TISSUE FROZEN IN OCT AS MIRROR IMAGE TO THE NIPPLE (D6) AND OF THE RANDOM QUADRANT SECTIONS (D21 THROUGH D24).

COMMENT: THIS SPECIMEN EXCEEDS THE MAXIMUM CAP/ASCO GUIDELINE OF 48 HOURS FORMALIN FIXATION.

PATH PROCEDURES

PROCEDURES:

88305/2, 88307, 88309, A BLK, B BLK/3, C BLK/13, D BLK/29

FINAL DIAGNOSIS

PART A RIGHT AXILLARY LEVEL 2 LYMPH NODE SAMPLING: METASTATIC CARCINOMA CONSISTENT WITH LOBULAR CARCINOMA OF PRIMARY BREAST ORIGIN INVOLVING 4 OF 4 LYMPH NODES WITH THE TUMOR REPLACING 80-90% OF THE CELLS IN EACH NODE AND THE LARGEST FOCUS OF TUMOR SPANNING A DISTANCE OF APPROXIMATELY 9 MM.

4/4 LN (level 2)

PART B RIGHT AXILLARY LEVEL 3 LYMPH NODE SAMPLING: METASTATIC

6/6 LN (level 3)

[page 4 of 4]
(Continued)

#eq

Sp type: SURGICAL P

M.D.

(Continued)

CARCINOMA IDENTIFIED IN 6 OF 6 LYMPH NODES.

PART C LEFT MASTECTOMY: SKIN AND FATTY BREAST TISSUE WITH FOCAL FIBROCYSTIC CHANGES PRESENT. NO EVIDENCE OF MALIGNANCY OR ATYPIA.

FCC (L)

PART D. RIGHT MODIFIED RADICAL MASTECTOMY: MULTICENTRIC IN SITU AND INFILTRATING LOBULAR CARCINOMA OF THE PLEOMORPHIC TYPE, NUCLEAR GRADE 2-3 OF 3 WITH A LOW MITOTIC INDEX WITH DOCUMENTED MICROSCOPIC EVIDENCE OF TUMOR SPANNING A DISTANCE OF AT LEAST 78 MM IN A SUPERIOR TO INFERIOR DIRECTION. THE TUMOR WAS 8 MM FROM THE CLOSEST DEEP MARGIN. METASTATIC CARCINOMA IDENTIFIED IN 8 OF 20 AXILLARY LYMPH NODES WITH THE LARGEST FOCUS OF TUMOR SPANNING A DISTANCE OF 20 MM AND FOCAL MICROSCOPIC PERINODAL SOFT TISSUE INVASION PRESENT.

Multicentric
LC 3/3/1
pleo
7.8cm.
⊖ margins

$$\frac{8}{20} \text{LN}(\text{level})$$

ENX

Signed Electronically signed by: _____

M.D.

ICD-10 Discrepancy		
ICD-9 Discrepancy		
ICD-9-CM Discrepancy		
ICD-9-CM History		
Discrepancy in Previous History Noted		
Discrepancy in History		
Discrepancy in Initials		
Discrepancy in Date		
Discrepancy in Date Reviewed		

Source: NCI Genomic Data Commons file 9414fc12-f346-4872-ae01-dbf45d7d1887 (TCGA-A2-A4RY.2D6815B5-7704-4D67-93D1-78EDD924F131.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).